Somatic mutation profile of tumor specimen 0DTYB5 from CCDI case PBCKDI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.3 years (2,681 days).
Specimen 0DTYB5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f473dcd-339a-4915-a984-c9c3b7ff0976.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTYAV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0d4b892-9e70-408a-a11c-985465e38d76

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DCC | c.562C>T p.R188* | Nonsense Mutation (SNP) | VAF 44/844 reads (5%) | catalogued as COSV59085082, COSV59130590; called by muse, mutect2
- C16orf71 | c.901+4T>A | Splice Region (SNP) | VAF 12/251 reads (5%) | called by muse, mutect2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 44/1150 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- ITPR1 | c.4597G>A p.V1533M (on ENST00000354582; = p.V1518M on NM_002222.7) | Missense Mutation (SNP) | VAF 56/1406 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 64/1376 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
